Surgical pathology report (de-identified scan), TCGA case TCGA-AP-A1DH, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site MSKCC, specimen TCGA-AP-A1DH-01A (Primary Tumor).

[page 1 of 2]
1CD-0-3

Adenocarcinoma, endometrioid, NOS 8380/3
Site Code: Endometrium C54.1

TSS Name/##:

1/12/11

fw

Specimens Submitted:

- 1: SP: Uterus, cervix, bilateral fallopian tubes and ovaries
- 2: SP: Abdominal pannus
- 3: SP: Left external iliac lymph node
- 4: SP: Left obturator lymph node
- 5: SP: Right external iliac lymph node
- 6: SP: Right obturator lymph nodes
- 7: SP: Right common iliac lymph nodes
- 8: SP: Portion of omentum

DIAGNOSIS:

- 1) UTERUS, CERVIX, BILATRAL FALLOPIAN TUBES AND OVARIES; TOTAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY:
- ADENOCARCINOMA OF ENDOMETRIUM, ENDOMETRIOID TYPE, FIGO GRADE III (> 50% SOLID GROWTH).
NUCLEAR GRADE 2.
- THE TUMOR INVADERS TO <HALF OF MYOMETRIUM.
- THE MAXIMAL THICKNESS OF MYOMETRIAL INVASION IS 9 MM.
- THE THICKNESS OF THE MYOMETRIUM IN THE AREA OF MAXIMAL TUMOR INVASION IS 22 MM.
- NO ENDOCERVICAL INVASION IS IDENTIFIED.
- NO VASCULAR INVASION IS IDENTIFIED.
- THE ENDOMETRIUM IS INACTIVE.
- THE MYOMETRIUM SHOWS ADENOMYOSIS AND SUBSEROUSAL LEIOMYOMA.
- ENDOCERVICAL POLYP.
- ALL ADNEXAL STRUCTURES ARE UNREMARKABLE.
- 2) ABDOMEN, PANNUS; PANNICULECTOMY:
- UNREMARKABLE SKIN AND SUBCUTANEOUS ADIPOSE TISSUE.
- 3) LYMPH NODES, LEFT, EXTERNAL ILIAC; EXCISION:
- SEVEN BENIGN LYMPH NODES (0/7).
- 4) LYMPH NODES, LEFT, OBTURATOR; EXCISION:

** Continued on next page **

Carc. in (Site)		

[page 2 of 2]
TSS Name/##:

- NINE BENIGN LYMPH NODES (0/9).

Page 2 of 5

- 5) LYMPH NODES, RIGHT, EXTERNAL ILIAC; EXCISION:
- FOUR BENIGN LYMPH NODES (0/4).
- 6) LYMPH NODES, RIGHT, OBTURATOR; EXCISION:
- FOUR BENIGN LYMPH NODES (0/4).
- 7) LYMPH NODE, RIGHT, COMMON ILIAC; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
- 8) OMENTUM; PARTIAL OMENTECTOMY:
- BENIGN ADIPOSE TISSUE.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Source: NCI Genomic Data Commons file fc7608ca-3f4c-4deb-bf12-16fb9b3d9e74 (TCGA-AP-A1DH.B77EE1CD-716C-4441-B4A9-CCCC37BD1379.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).